CPTAC case C3N-00681 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0ae2470e-b710-465f-ac38-8e1d8ff19a03

Demographics
Sex at birth: male; Race: white; Year of birth: 1986; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 31.8 years (11,606 days); Year of diagnosis: 2017; Days to last known disease status: 1,799 days (4.9 years); Days to last follow up: 1,799 days (4.9 years).

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 370, day 720, day 994, day 1,386, day 1,799.

Other clinical attributes
- Weight: 75 kg; Height: 184 cm; BMI: 22.15.

Biospecimens (3 samples)
- Sample C3N-00681-50: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3N-00681-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Time between excision and freezing: 171 minutes.
- Sample C3N-00681-56: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 2 days; Time between excision and freezing: 171 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
